Gene-level copy-number profile of specimen HCM-SANG-0546-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0546-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0546-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c0b46c47-b648-4dac-b631-166ec4540114.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0546-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/395fac3e-46dd-41b7-9540-9be3a4fd17dc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,336; copy number 2: 28,403; copy number 3: 21,740; copy number 4: 4,077; copy number 5: 1,254; copy number 6: 632; copy number 7: 33; copy number 8: 82; copy number 9: 13; copy number 10: 76; copy number 11: 92; copy number 12: 1; copy number 21: 12; copy number 22: 20; copy number 23: 39; copy number 24: 39; copy number 25: 14; copy number 26: 1; copy number 33: 1; copy number 42: 15; copy number 44: 13; copy number 51: 16; copy number 54: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,356 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,708,148, 75 genes, copy number 5 (broad region; genes not listed).
- chr5:107,376,889–113,595,285, 78 genes, copy number 5–10 (broad region; genes not listed).
- chr6:33,620,365–36,024,868, 72 genes, copy number 6–10 (broad region; genes not listed).
- chr8:120,445,400–137,105,458, 226 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr9:136,006,537–136,373,681, 12 genes, copy number 5: NACC2, LINC02846, TMEM250, AL138781.1, LHX3, QSOX2, CCDC187, CR392000.1, DKFZP434A062, GPSM1, DNLZ, CARD9.
- chr9:136,612,024–137,578,925, 92 genes, copy number 5 (broad region; genes not listed).
- chr9:137,605,744–137,711,018, 1 gene, copy number 5 (within-gene range 4–5): AL590627.2.
- chr9:137,618,992–137,870,016, 1 gene, copy number 5 (within-gene range 4–5): EHMT1.
- chr9:137,776,539–137,838,516, 2 genes, copy number 5: AL590627.1, MIR602.
- chr10:14,061–32,269,474, 532 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:24,810,024–29,381,189, 98 genes, copy number 6–42 (broad region; genes not listed).
- chr12:30,169,881–34,249,958, 103 genes, copy number 6 (broad region; genes not listed).
- chr16:29,992,330–31,382,999, 128 genes, copy number 5 (broad region; genes not listed).
- chr18:20,946,906–45,683,688, 309 genes, copy number 6–25 (within-gene range 1–25) (broad region; genes not listed).
- chr18:48,475,487–49,599,185, 33 genes, copy number 26–54: RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG.
- chr20:87,250–16,053,197, 288 genes, copy number 5–6 (within-gene range 1–6) (broad region; genes not listed).
- chr20:15,280,764–26,251,546, 240 genes, copy number 5–6 (broad region; genes not listed).
- chr20:57,895,394–61,940,617, 66 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,824. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
